Gene-level copy-number profile of tumor specimen ALCH-B3Z8-TTP1-A from ALCHEMIST case ALCH-B3Z8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Age at diagnosis: 57.9 years (21,131 days).
Specimen ALCH-B3Z8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a85e7dcf-447b-477b-a96c-a5d14afb71ba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3Z8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/0e0625a7-7b96-48ce-b4dd-af7747fb2ba4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 7,600; copy number 2: 42,859; copy number 3: 7,322; copy number 4: 445; copy number 5: 15; copy number 6: 1; copy number 7: 67; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–1): PRAMEF29P.
- chr1:13,254,212–13,285,174, 4 genes: PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8.
- chr2:131,492,813–131,521,573, 1 gene: SMPD4BP.
- chr2:232,368,576–232,382,889, 3 genes: AC068134.3, ALPP, AC068134.1.
- chr3:50,279,087–50,299,416, 4 genes (within-gene range 0–2): LSMEM2, IFRD2, HYAL3, NAA80.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr3:130,034,553–130,035,539, 1 gene: OR7E21P.
- chr3:130,089,433–130,094,304, 1 gene (within-gene range 0–2): LINC02014.
- chr4:49,203,171–49,203,726, 1 gene: AC118282.3.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:177,357,924–177,372,596, 1 gene: RGS14.
- chr7:128,937,457–128,950,038, 1 gene: IRF5.
- chr7:149,714,781–149,734,575, 1 gene: KRBA1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr11:74,696,429–74,738,796, 4 genes: CHRDL2, AP001324.3, MIR4696, AP001324.2.
- chr15:25,172,635–25,247,426, 41 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:16,414,524–16,492,193, 9 genes: AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:63,477,061–63,521,848, 3 genes: ACE, AC113554.1, ACE3P.
- chr19:281,040–291,403, 1 gene: PLPP2.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 85 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 8 (within-gene range 1–8): PRAMEF6, PRAMEF28P.
- chr4:1,056,250–1,340,147, 12 genes, copy number 5: RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA.
- chr4:1,402,932–1,406,442, 1 gene, copy number 6: NKX1-1.
- chr4:7,758,714–7,939,926, 2 genes, copy number 5 (within-gene range 2–5): AFAP1, AC112254.1.
- chr19:46,039,748–46,077,118, 1 gene, copy number 5: IGFL4.
- chr20:62,841,005–63,936,031, 67 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,575. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
